Somatic mutation profile of tumor specimen TARGET-30-PATNGD-01A (aliquot TARGET-30-PATNGD-01A-01D) from TARGET case TARGET-30-PATNGD, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.9 years (1,066 days).
Specimen TARGET-30-PATNGD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99b16a00-310b-4d02-a83a-7889eec59f3d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATNGD-10A (Blood Derived Normal), aliquot TARGET-30-PATNGD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a4607c3-d9ef-4741-835c-ad2c8599cd1d

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY5 | c.2759C>A p.A920D | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV59204541; called by muse, mutect2, varscan2
- MYH2 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 30/104 reads (29%) | catalogued as rs750232956; called by muse, varscan2
- CCDC8 | c.1559T>A p.V520E | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TTC23 | c.-692G>A | 5'UTR (SNP) | VAF 99/233 reads (42%) | catalogued as COSV50444446; called by muse, mutect2, varscan2
